Somatic mutation profile of tumor specimen TCGA-CW-5581-01A (aliquot TCGA-CW-5581-01A-02D-1534-10) from TCGA case TCGA-CW-5581, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 44.3 years (16,195 days).
Specimen TCGA-CW-5581-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b876365-ed66-4aaf-a450-7db20f7d5e65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-5581-11A (Solid Tissue Normal), aliquot TCGA-CW-5581-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8c409f9-86b2-4557-909e-c37f0d9282dd

The open-access MAF lists 57 somatic variants for this specimen: 49 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 33, Silent 8, Frame Shift Del 6, Nonsense Mutation 5, In Frame Del 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.1212dup p.G405Rfs*48 (on ENST00000219054; = p.G326Rfs*48 on NM_001308169.2) | Frame Shift Ins (INS) | VAF 110/330 reads (33%) | catalogued as rs755296455; called by mutect2, pindel, varscan2
- AQR | c.372A>C p.K124N | Missense Mutation (SNP) | VAF 110/491 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV50029699; called by muse, mutect2, varscan2
- CAPN6 | c.1077C>A p.C359* | Nonsense Mutation (SNP) | VAF 89/180 reads (49%) | catalogued as COSV60693895; called by muse, mutect2, varscan2
- CD82 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.748); catalogued as rs1326323470, COSV57033929; called by muse, mutect2
- CDH2 | c.2567T>A p.L856* | Nonsense Mutation (SNP) | VAF 88/351 reads (25%) | catalogued as COSV52272147; called by muse, mutect2, varscan2
- CEP152 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 132/640 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV57856738; called by muse, mutect2, varscan2
- CSMD2 | c.2816G>T p.G939V | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748249909, COSV53880555; called by mutect2, varscan2
- CYP17A1 | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64004708; called by muse, mutect2, varscan2
- DENR | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 181/697 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54887214, COSV99757429; called by muse, mutect2, varscan2
- EPHA6 | c.2043G>C p.E681D (on ENST00000389672 / NM_001080448.3; = p.E73D on NM_173655.4) | Missense Mutation (SNP) | VAF 148/846 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV67559418; called by muse, mutect2, varscan2
- ERVFRD-1 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65368625; called by muse, mutect2, varscan2
- FAS | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 94/407 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV58238198; called by muse, mutect2, varscan2
- IGFBP4 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV54096623; called by muse, mutect2, varscan2
- JMJD1C | c.2783C>G p.S928C | Missense Mutation (SNP) | VAF 132/577 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59512838; called by muse, mutect2, varscan2
- JMJD4 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 49/187 reads (26%) | catalogued as COSV59916946; called by muse, mutect2, varscan2
- KCNH3 | c.351del p.N118Mfs*10 | Frame Shift Del (DEL) | VAF 84/374 reads (22%) | catalogued as COSV57790811, COSV57791820; called by mutect2, pindel, varscan2
- KIAA0319 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV65496399; called by muse, mutect2, varscan2
- LPIN1 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 108/475 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs367859334; called by muse, mutect2, varscan2
- LRFN5 | c.1065T>A p.F355L | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53243645; called by muse, mutect2
- LTBP1 | c.4983C>G p.V1661= (on ENST00000404816 / NM_206943.4; = p.V1335= on NM_000627.4) | Splice Region (SNP) | VAF 133/476 reads (28%) | catalogued as COSV55375631, COSV55386238; called by muse, mutect2, varscan2
- LYG1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 65/326 reads (20%) | catalogued as COSV57915168; called by muse, mutect2, varscan2
- MAP3K15 | c.2502C>G p.I834M | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58826099; called by muse, mutect2, varscan2
- MPP2 | c.342G>C p.E114D (on ENST00000461854 / NM_001278372.2; = p.E90D on NM_005374.5) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV52233019; called by muse, mutect2, varscan2
- MYLIP | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 118/466 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62766323; called by muse, mutect2, varscan2
- NHP2 | c.402G>C p.E134D | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51070807; called by muse, mutect2, varscan2
- NMT2 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65381411; called by muse, mutect2
- OR5AR1 | c.850A>T p.M284L | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs766110851, COSV57252821, COSV57254197; called by muse, mutect2, varscan2
- OR5L1 | c.636G>T p.M212I | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV61732697, COSV61733111, COSV61733957; called by muse, mutect2, varscan2
- PCDH1 | c.2968A>T p.K990* | Nonsense Mutation (SNP) | VAF 33/185 reads (18%) | catalogued as COSV54611114; called by muse, mutect2, varscan2
- PLCG2 | c.2288G>A p.S763N | Missense Mutation (SNP) | VAF 84/452 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.61); catalogued as COSV63867535; called by muse, varscan2
- RNASE12 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.876); catalogued as COSV60087274; called by muse, mutect2
- RTKN2 | c.1487A>C p.D496A | Missense Mutation (SNP) | VAF 118/461 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV59521418; called by muse, mutect2, varscan2
- SEPTIN4 | c.1154T>A p.M385K | Missense Mutation (SNP) | VAF 272/1147 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.283); catalogued as COSV58727124; called by muse, mutect2, varscan2
- SLITRK6 | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 87/322 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs775661521, COSV68389372, COSV68389515; called by muse, mutect2, varscan2
- THBS3 | c.948C>A p.D316E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64248482; called by muse, mutect2, varscan2
- THBS3 | c.947A>T p.D316V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64248488; called by muse, mutect2, varscan2
- TNNI1 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV60188909; called by muse, mutect2, varscan2
- UNC5B | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.11); catalogued as COSV58974502; called by muse, mutect2, varscan2
- USP34 | c.7620C>A p.D2540E | Missense Mutation (SNP) | VAF 280/1143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV68398194; called by muse, mutect2, varscan2
- YTHDC2 | c.2959G>T p.D987Y | Missense Mutation (SNP) | VAF 132/666 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs757994040, COSV50736718; called by muse, mutect2, varscan2
- ZNF555 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374516727, COSV62072795; called by muse, mutect2, varscan2
- ABCG1 | c.586_588+13del p.X196_splice | Splice Site (DEL) | VAF 90/605 reads (15%) | called by mutect2, pindel
- ARMCX5 | c.773_775del p.P258del | In Frame Del (DEL) | VAF 48/116 reads (41%) | called by pindel, varscan2
- ATP6V1A | c.1835del p.F612Sfs*62 | Frame Shift Del (DEL) | VAF 125/524 reads (24%) | called by mutect2, pindel, varscan2
- CBLB | c.2225del p.M742Sfs*2 | Frame Shift Del (DEL) | VAF 105/341 reads (31%) | called by mutect2, pindel*, varscan2
- CCDC127 | c.348_353del p.K117_K118del | In Frame Del (DEL) | VAF 65/308 reads (21%) | called by mutect2, pindel, varscan2
- KDM5C | c.4242_4252del p.D1414Efs*54 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- TAS2R13 | c.497del p.N166Ifs*4 | Frame Shift Del (DEL) | VAF 83/398 reads (21%) | called by mutect2, pindel, varscan2
- ZBTB41 | c.1331_1332del p.F444Sfs*3 | Frame Shift Del (DEL) | VAF 93/475 reads (20%) | called by mutect2, pindel, varscan2
- ESRP2 | c.1413G>T p.G471= (on ENST00000565858 / NM_001365264.1; = p.G461= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/209 reads (5%) | catalogued as COSV52172015; called by muse, mutect2
- FLRT2 | c.1563C>T p.N521= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs754192258, COSV58136436; called by muse, mutect2, varscan2
- MGAM | c.2835C>A p.L945= | Silent (SNP) | VAF 101/355 reads (28%) | catalogued as COSV72073646; called by muse, mutect2, varscan2
- PPP6R3 | c.459T>A p.I153= | Silent (SNP) | VAF 195/821 reads (24%) | catalogued as COSV55721612; called by muse, mutect2, varscan2
- PPRC1 | c.4390A>C p.R1464= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53383169; called by muse, mutect2
- SOCS7 | c.1446A>G p.P482= | Silent (SNP) | VAF 208/848 reads (25%) | catalogued as rs587650322; called by muse, mutect2
- SPATC1L | c.492G>A p.S164= (on ENST00000291672 / NM_001142854.2; = p.S10= on NM_032261.5) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs747760174, COSV52431966; called by muse, mutect2, varscan2
- TRMT61B | c.1425A>G p.Q475= | Silent (SNP) | VAF 215/781 reads (28%) | catalogued as rs377283695; called by muse, mutect2, varscan2
